Somatic mutation profile of tumor specimen TARGET-30-PANLET-01A (aliquot TARGET-30-PANLET-01A-01D) from TARGET case TARGET-30-PANLET, project TARGET-NBL (Neuroblastoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Ganglioneuroblastoma; Tissue or organ of origin: Adrenal gland, NOS; Age at diagnosis: 5.4 years (1,973 days).
Specimen TARGET-30-PANLET-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f177f666-c5fa-47ed-9b87-44e09addccbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-30-PANLET-10A (Blood Derived Normal), aliquot TARGET-30-PANLET-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f99c245-79fc-4874-a4e4-17f745340c69

The open-access MAF lists 27 somatic variants for this specimen: 20 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 18, Silent 7, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CACNA1B | c.398C>T p.T133M | Missense Mutation (SNP) | VAF 33/77 reads (43%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs767767631, COSV53113689; called by muse, mutect2, varscan2
- CLEC16A | c.1366C>T p.Q456* | Nonsense Mutation (SNP) | VAF 30/52 reads (58%) | catalogued as COSV68497857; called by muse, mutect2, varscan2
- FLG | c.1397G>A p.G466E | Missense Mutation (SNP) | VAF 127/304 reads (42%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.971); catalogued as COSV64236425, COSV64244942; called by muse, mutect2, varscan2
- FRAS1 | c.6067G>T p.V2023F | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.127); catalogued as COSV53589049; called by muse, mutect2, varscan2
- IL1A | c.79C>A p.H27N | Missense Mutation (SNP) | VAF 41/75 reads (55%) | SIFT tolerated (0.11); PolyPhen benign (0.196); catalogued as COSV54518843; called by muse, mutect2, varscan2
- IPCEF1 | c.1170C>G p.Y390* | Nonsense Mutation (SNP) | VAF 31/63 reads (49%) | catalogued as COSV54540604; called by muse, mutect2, varscan2
- IQUB | c.1204G>T p.D402Y | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61236863; called by muse, mutect2, varscan2
- LPO | c.1081G>T p.A361S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.178); catalogued as COSV51856790; called by muse, mutect2, varscan2
- MYH10 | c.653T>A p.L218H | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52594991; called by muse, mutect2, varscan2
- NCAN | c.3653C>T p.P1218L | Missense Mutation (SNP) | VAF 22/47 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53046754; called by muse, mutect2, varscan2
- OVGP1 | c.1705G>T p.V569L | Missense Mutation (SNP) | VAF 78/163 reads (48%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.056); catalogued as COSV63857508, COSV63858588; called by muse, mutect2, varscan2
- PHF10 | c.442G>C p.D148H | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV59321035; called by muse, mutect2, varscan2
- PRDM16 | c.517C>T p.R173C | Missense Mutation (SNP) | VAF 44/125 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs1452901414, COSV54578558; called by muse, mutect2, varscan2
- RFPL4B | c.527C>A p.P176H | Missense Mutation (SNP) | VAF 43/101 reads (43%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV71437092, COSV71437149; called by muse, mutect2, varscan2
- RNF215 | c.892C>T p.R298W | Missense Mutation (SNP) | VAF 51/135 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.23); catalogued as rs145777306; called by muse, mutect2, varscan2
- SH3GL2 | c.1004A>T p.H335L | Missense Mutation (SNP) | VAF 20/36 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV66047650; called by muse, mutect2, varscan2
- TAFA2 | c.82G>T p.V28L | Missense Mutation (SNP) | VAF 22/65 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV69172348; called by muse, mutect2, varscan2
- ZNF19 | c.977A>T p.E326V | Missense Mutation (SNP) | VAF 25/78 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55506876; called by muse, mutect2, varscan2
- ZNF575 | c.176C>A p.P59H | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV58564285; called by muse, mutect2
- MUC5AC | c.13739C>A p.A4580D | Missense Mutation (SNP) | VAF 55/99 reads (56%) | SIFT tolerated (0.53); called by muse, mutect2, varscan2
- ILDR2 | c.1131C>T p.V377= | Silent (SNP) | VAF 128/269 reads (48%) | catalogued as COSV54828542; called by muse, mutect2, varscan2
- ISOC1 | c.207G>T p.V69= | Silent (SNP) | VAF 25/55 reads (45%) | catalogued as COSV51491035, COSV51491700; called by muse, mutect2, varscan2
- RNF149 | c.1119C>A p.P373= | Silent (SNP) | VAF 50/132 reads (38%) | catalogued as COSV54862868, COSV54863297; called by muse, mutect2, varscan2
- RXRG | c.1377G>A p.P459= | Silent (SNP) | VAF 43/106 reads (41%) | catalogued as rs149087358; called by muse, mutect2, varscan2
- TEX15 | c.4653G>A p.S1551= (on ENST00000256246; = p.S1934= on NM_001350162.2) | Silent (SNP) | VAF 49/108 reads (45%) | catalogued as rs996880415, COSV56341515; called by muse, mutect2, varscan2
- TNS4 | c.801G>T p.R267= | Silent (SNP) | VAF 56/290 reads (19%) | catalogued as COSV54183365; called by muse, varscan2
- WNK4 | c.1677G>A p.E559= | Silent (SNP) | VAF 79/366 reads (22%) | catalogued as COSV55901465; called by muse, mutect2, varscan2
